Somatic mutation profile of tumor specimen TCGA-B0-5812-01A (aliquot TCGA-B0-5812-01A-11D-1669-08) from TCGA case TCGA-B0-5812, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 53.7 years (19,600 days).
Specimen TCGA-B0-5812-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 43ef696a-67e9-4144-ab79-5efc67541bea.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B0-5812-11A (Solid Tissue Normal), aliquot TCGA-B0-5812-11A-01D-1669-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/805ecb30-b569-4e6b-a9b8-1651cfda6fc8

The open-access MAF lists 45 somatic variants for this specimen: 35 protein-altering or splice-affecting, 10 silent.
By variant classification: Missense Mutation 28, Silent 10, Nonsense Mutation 5, Frame Shift Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- VHL | c.433C>T p.Q145* | Nonsense Mutation (SNP) | VAF 44/178 reads (25%) | catalogued as rs749704215, CM994243, COSV56549953; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADAMTS5 | c.2313C>A p.F771L | Missense Mutation (SNP) | VAF 43/208 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.112); catalogued as COSV53184357; called by muse, mutect2, varscan2
- APC | c.1813G>A p.D605N | Missense Mutation (SNP) | VAF 21/139 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0.131); catalogued as rs1060503278, COSV57376234; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ARHGAP35 | c.676G>A p.V226M | Missense Mutation (SNP) | VAF 7/88 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV68335221; called by muse, mutect2
- ARHGEF7 | c.1672G>T p.V558L (on ENST00000375741 / NM_001113511.2; = p.V380L on NM_003899.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/151 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.556); catalogued as COSV54550223; called by muse, mutect2, varscan2
- BAHD1 | c.2200A>C p.K734Q | Missense Mutation (SNP) | VAF 43/167 reads (26%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.812); catalogued as rs974451078, COSV60379413; called by muse, mutect2, varscan2
- CEP120 | c.1457C>G p.A486G | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.505); catalogued as COSV60268218; called by muse, mutect2, varscan2
- CEP120 | c.1456G>T p.A486S | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT tolerated (0.27); PolyPhen benign (0.288); catalogued as COSV60268236; called by muse, mutect2, varscan2
- CPLANE1 | c.9137C>G p.P3046R | Missense Mutation (SNP) | VAF 21/101 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV57071903; called by muse, mutect2, varscan2
- DLG2 | c.1828T>A p.L610M | Missense Mutation (SNP) | VAF 7/132 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0.23); catalogued as rs1485356954, COSV54678944; called by muse, mutect2
- EDNRB | c.1471T>G p.L491V (on ENST00000377211 / NM_001201397.1; = p.L401V on NM_000115.5) | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV57520076, COSV57520815; called by muse, mutect2, varscan2
- EML1 | c.1188C>A p.Y396* | Nonsense Mutation (SNP) | VAF 23/153 reads (15%) | catalogued as rs754110185, COSV51751552; called by muse, mutect2, varscan2
- FIP1L1 | c.784T>C p.S262P | Missense Mutation (SNP) | VAF 27/119 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0.006); catalogued as rs587778363, COSV60999268; ClinVar: not provided; called by muse, mutect2, varscan2
- GRM5 | c.1439A>C p.D480A | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV59625289; called by muse, mutect2, varscan2
- HYOU1 | c.415A>T p.S139C | Missense Mutation (SNP) | VAF 24/122 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV68217199; called by muse, mutect2, varscan2
- LAMB1 | c.1582C>T p.Q528* | Nonsense Mutation (SNP) | VAF 7/41 reads (17%) | catalogued as rs375014512; called by muse, mutect2, varscan2
- LRFN2 | c.777C>G p.D259E | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV57825653, COSV57833566; called by muse, mutect2, varscan2
- LZTS3 | c.550A>T p.N184Y | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.271); catalogued as COSV61278836; called by muse, mutect2, varscan2
- MADD | c.2096G>A p.R699H | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT tolerated, low confidence (0.14); PolyPhen probably damaging (0.991); catalogued as rs751993844, COSV60629198; called by muse, mutect2, varscan2
- MAGI2 | c.3658C>T p.R1220* | Nonsense Mutation (SNP) | VAF 16/254 reads (6%) | catalogued as COSV62692594; called by muse, mutect2
- MLEC | c.496G>A p.D166N | Missense Mutation (SNP) | VAF 38/183 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as COSV57329397, COSV57329841; called by muse, mutect2, varscan2
- MSR1 | c.791C>A p.T264N | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs143967440, COSV50529289; called by muse, mutect2, varscan2
- NCKAP5 | c.4505C>A p.P1502H | Missense Mutation (SNP) | VAF 28/96 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.591); catalogued as COSV58470707; called by muse, mutect2, varscan2
- PKHD1 | c.8341A>G p.K2781E | Missense Mutation (SNP) | VAF 21/87 reads (24%) | SIFT tolerated (0.23); PolyPhen benign (0.272); catalogued as COSV61891983; called by muse, mutect2, varscan2
- RIMS2 | c.304G>C p.D102H | Missense Mutation (SNP) | VAF 31/149 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68497893; called by muse, mutect2, varscan2
- SLC41A2 | c.880G>C p.G294R | Missense Mutation (SNP) | VAF 36/165 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs1373985892, COSV51610262; called by muse, mutect2, varscan2
- SMARCA4 | c.3379G>T p.D1127Y | Missense Mutation (SNP) | VAF 16/206 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV60785941, COSV60807047; called by muse, mutect2
- ST8SIA1 | c.854G>A p.G285D | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.102); catalogued as COSV53958435; called by muse, mutect2
- STAC2 | c.1131+2T>G p.X377_splice | Splice Site (SNP) | VAF 24/108 reads (22%) | catalogued as rs1457502546, COSV61066463, COSV61066517; called by muse, mutect2, varscan2
- TCN2 | c.1142T>A p.L381* | Nonsense Mutation (SNP) | VAF 20/93 reads (22%) | catalogued as COSV53192847; called by muse, mutect2, varscan2
- TGM5 | c.890G>T p.R297L (on ENST00000220420 / NM_201631.4; = p.R215L on NM_004245.4) | Missense Mutation (SNP) | VAF 14/92 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55011898; called by muse, mutect2, varscan2
- TUBB2B | c.41A>G p.N14S | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.109); catalogued as COSV52534406; called by muse, mutect2, varscan2
- UBE4B | c.491A>C p.K164T | Missense Mutation (SNP) | VAF 18/93 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.398); catalogued as COSV53541036; called by muse, mutect2, varscan2
- VWA3B | c.1405A>G p.K469E | Missense Mutation (SNP) | VAF 29/104 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.214); catalogued as rs1045723026, COSV68246162; called by muse, mutect2, varscan2
- PBRM1 | c.174_183del p.D59Mfs*33 | Frame Shift Del (DEL) | VAF 14/77 reads (18%) | called by mutect2, pindel, varscan2
- ADGRL2 | c.3900T>C p.A1300= (on ENST00000370717 / NM_001366005.1; = p.A1244= on NM_012302.4) | Silent (SNP) | VAF 6/112 reads (5%) | catalogued as COSV54685603; called by muse, mutect2
- ERICH1 | c.804C>T p.D268= | Silent (SNP) | VAF 21/118 reads (18%) | catalogued as rs1387504904, COSV50640520; called by muse, mutect2, varscan2
- LAMC3 | c.2553C>T p.Y851= | Silent (SNP) | VAF 19/113 reads (17%) | catalogued as rs748622966, COSV63092292; ClinVar: likely benign; called by muse, mutect2, varscan2
- LRP1B | c.1515T>A p.T505= | Silent (SNP) | VAF 9/92 reads (10%) | catalogued as COSV67266523; called by muse, mutect2, varscan2
- MCF2L2 | c.3123G>A p.Q1041= | Silent (SNP) | VAF 12/112 reads (11%) | catalogued as COSV61060249; called by muse, mutect2, varscan2
- NLGN1 | c.1782T>G p.V594= | Silent (SNP) | VAF 25/149 reads (17%) | catalogued as COSV64344874; called by muse, mutect2, varscan2
- NUP133 | c.84G>C p.T28= | Silent (SNP) | VAF 7/17 reads (41%) | catalogued as COSV54574813; called by muse, mutect2, varscan2
- SAPCD2 | c.1116T>C p.I372= | Silent (SNP) | VAF 4/11 reads (36%) | catalogued as COSV68836590; called by muse, mutect2, varscan2
- SLC16A5 | c.1143A>T p.P381= | Silent (SNP) | VAF 8/48 reads (17%) | catalogued as COSV61676750; called by muse, varscan2
- SLC39A12 | c.453G>A p.R151= | Silent (SNP) | VAF 14/115 reads (12%) | catalogued as rs1554848426, COSV66202021; called by muse, mutect2, varscan2
